Somatic mutation profile of tumor specimen HCM-BROD-0116-C16-01A (aliquot HCM-BROD-0116-C16-01A-11D-A79C-36) from HCMI case HCM-BROD-0116-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.7 years (20,721 days).
Specimen HCM-BROD-0116-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddd9dc68-9b5a-46a4-9fa3-6296f09b4a64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0116-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0116-C16-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea64ff5d-9bc5-4804-8758-4bc74df51fe4

The open-access MAF lists 88 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Nonsense Mutation 3, Frame Shift Del 2, Intron 2, Translation Start Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 26/168 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- SMAD4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 40/239 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767342, CM100517, COSV61684465, COSV61684539, COSV61685012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 97/419 reads (23%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 33/394 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1277216051; called by muse, mutect2
- ANKRD30B | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs752127097, COSV62814186, COSV62825406; called by muse, mutect2
- ANO3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs764319060, COSV56783014; called by muse, mutect2, varscan2
- BAZ1B | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs1310053804, COSV59994327; called by muse, mutect2, varscan2
- CDH26 | c.2347G>A p.V783I (on ENST00000348616 / NM_177980.4; = p.V116I on NM_021810.6) | Missense Mutation (SNP) | VAF 54/436 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs201751321, COSV54852971, COSV54853000; called by muse, mutect2, varscan2
- COL6A6 | c.5567G>A p.R1856Q | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99070683; called by muse, mutect2
- DACH2 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100912689; called by muse, mutect2, varscan2
- DNAH7 | c.5798T>C p.L1933S | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56781724; called by muse, mutect2, varscan2
- FAM126B | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV53773579; called by muse, mutect2, varscan2
- FAM47B | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV61455827; called by muse, mutect2, varscan2
- FRMPD4 | c.2003C>A p.T668N | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376545795; ClinVar: benign; called by muse, mutect2, varscan2
- GPT | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 85/451 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs762924568, COSV52953439; called by muse, mutect2, varscan2
- KCNH6 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 66/418 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs549333382, COSV59006357; called by muse, mutect2, varscan2
- MEGF10 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248875; called by muse, mutect2
- NLRP9 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs143466064, COSV60463338; called by muse, mutect2, varscan2
- P2RY14 | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56373280; called by muse, mutect2, varscan2
- PANK4 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 129/480 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279771228; called by muse, mutect2, varscan2
- PCLO | c.12179C>T p.A4060V | Missense Mutation (SNP) | VAF 82/541 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs370449283, COSV61659259; called by muse, mutect2, varscan2
- PRKAA1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs375372236; called by muse, mutect2, varscan2
- SOX17 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 152/782 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1010687929, COSV52024261; called by muse, mutect2, varscan2
- SVEP1 | c.3335A>G p.E1112G | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1369597111; called by muse, mutect2
- TAF11L13 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs186785660; called by muse, mutect2, varscan2
- TEKT3 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs1398296925; called by muse, mutect2, varscan2
- TET1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV65388374; called by muse, mutect2, varscan2
- TMCC2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 91/660 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781304243, COSV58006520; called by muse, mutect2, varscan2
- TMEM108 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 87/426 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as rs866075699, COSV58883543; called by muse, mutect2, varscan2
- TNNT1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99402997; called by muse, mutect2, varscan2
- TYW1 | c.260C>G p.T87S | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs754483179; called by muse, mutect2, varscan2
- VPS13C | c.9486C>T p.V3162= (on ENST00000644861 / NM_020821.3; = p.V3119= on NM_017684.5) | Splice Region (SNP) | VAF 16/190 reads (8%) | catalogued as rs368946798; called by muse, mutect2
- ZIC1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 119/709 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.475); catalogued as rs375971584; called by muse, mutect2, varscan2
- ZNF814 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs563533612; called by muse, mutect2
- ZNF883 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs752559120; called by muse, mutect2, varscan2
- BTBD2 | c.1199_1200dup p.I401Afs*21 | Frame Shift Ins (INS) | VAF 67/480 reads (14%) | called by mutect2, pindel, varscan2
- CCDC15 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCPG1 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK8 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- CSMD3 | c.8272T>C p.S2758P (on ENST00000297405 / NM_001363185.1; = p.S2589P on NM_052900.3) | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DMC1 | c.875T>G p.I292S | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by mutect2, varscan2
- DNMT1 | c.2717A>T p.E906V | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- EML5 | c.3701A>G p.Y1234C | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETV1 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- HBE1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HFM1 | c.3671C>T p.S1224L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JAKMIP1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 102/657 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- JHY | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.799); called by mutect2, varscan2
- KRTAP4-5 | c.212G>C p.C71S | Missense Mutation (SNP) | VAF 119/857 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MITD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 43/253 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- NR3C2 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 82/481 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- OR2L2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 65/391 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2
- OR9H1P | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PKD2 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- PRRX2 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRF2 | c.3090del p.W1031Gfs*2 | Frame Shift Del (DEL) | VAF 37/293 reads (13%) | called by mutect2, pindel, varscan2
- SERPINI2 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 85/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SF3B6 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMG1 | c.8194G>A p.A2732T | Missense Mutation (SNP) | VAF 59/461 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SMOC2 | c.1318A>G p.R440G (on ENST00000356284 / NM_001166412.2; = p.R451G on NM_022138.3) | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SUGT1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TENM2 | c.4248G>A p.W1416* (on ENST00000518659 / NM_001122679.2; = p.W1177* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 56/297 reads (19%) | called by muse, mutect2, varscan2
- THSD7A | c.426del p.K142Nfs*14 | Frame Shift Del (DEL) | VAF 68/532 reads (13%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 46/258 reads (18%) | called by muse, mutect2, varscan2
- ZNF14 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 64/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF18 | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGXT | c.855G>A p.E285= | Silent (SNP) | VAF 36/351 reads (10%) | called by muse, mutect2, varscan2
- ANTKMT | c.342G>A p.A114= | Silent (SNP) | VAF 93/547 reads (17%) | catalogued as rs745533194; called by muse, mutect2, varscan2
- ARID5B | c.3318G>A p.L1106= | Silent (SNP) | VAF 55/404 reads (14%) | called by muse, mutect2, varscan2
- CCDC116 | c.990C>T p.R330= | Silent (SNP) | VAF 52/578 reads (9%) | catalogued as rs768637483, COSV53037200; called by muse, mutect2
- DACT2 | c.1839G>A p.V613= | Silent (SNP) | VAF 95/580 reads (16%) | called by muse, mutect2, varscan2
- DNAH11 | c.1515C>T p.H505= | Silent (SNP) | VAF 44/488 reads (9%) | catalogued as rs773061951; called by muse, mutect2
- ENDOU | c.261C>A p.P87= (on ENST00000422538 / NM_001172439.2; = p.P46= on NM_006025.4) | Silent (SNP) | VAF 64/296 reads (22%) | called by muse, mutect2, varscan2
- GABRB3 | c.675C>T p.F225= | Silent (SNP) | VAF 48/210 reads (23%) | catalogued as rs201004195; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC6 | c.343C>T p.L115= | Silent (SNP) | VAF 57/386 reads (15%) | catalogued as COSV51548086; called by muse, mutect2, varscan2
- MYO18A | c.2409C>T p.R803= | Silent (SNP) | VAF 55/406 reads (14%) | catalogued as rs764232569, COSV62870063; called by muse, varscan2
- NANOG | c.843T>C p.T281= | Silent (SNP) | VAF 38/335 reads (11%) | catalogued as rs1391412144; called by muse, mutect2, varscan2
- NAV3 | c.5493C>T p.I1831= (on ENST00000397909 / NM_001024383.2; = p.I1809= on NM_014903.6) | Silent (SNP) | VAF 34/302 reads (11%) | called by muse, mutect2, varscan2
- OR2L3 | c.636T>A p.A212= | Silent (SNP) | VAF 112/526 reads (21%) | called by muse, mutect2, varscan2
- PCNX2 | c.3507G>A p.R1169= | Silent (SNP) | VAF 44/275 reads (16%) | called by muse, mutect2
- PNISR | c.1743A>G p.K581= | Silent (SNP) | VAF 30/253 reads (12%) | called by muse, mutect2, varscan2
- SOGA1 | c.4284G>A p.S1428= | Silent (SNP) | VAF 69/599 reads (12%) | catalogued as rs537207073, COSV52931622; called by muse, mutect2, varscan2
- TEX14 | c.1878C>T p.F626= (on ENST00000240361 / NM_001201457.2; = p.F620= on NM_031272.5) | Silent (SNP) | VAF 62/429 reads (14%) | catalogued as rs374631413; called by muse, mutect2, varscan2
- TRIM42 | c.1791C>T p.N597= | Silent (SNP) | VAF 76/401 reads (19%) | catalogued as rs1021590216, COSV53887584; called by muse, mutect2, varscan2
- UBTFL1 | c.354C>T p.Y118= | Silent (SNP) | VAF 58/278 reads (21%) | called by muse, mutect2, varscan2
- VN1R2 | c.852C>T p.I284= | Silent (SNP) | VAF 44/401 reads (11%) | catalogued as rs988507744; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-32493A>G | Intron (SNP) | VAF 44/291 reads (15%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31210C>T | Intron (SNP) | VAF 62/420 reads (15%) | catalogued as rs771642512, COSV55154917; called by muse, mutect2, varscan2
